Somatic mutation profile of tumor specimen TCGA-05-4402-01A (aliquot TCGA-05-4402-01A-01D-1265-08) from TCGA case TCGA-05-4402, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 57.0 years (20,819 days).
Specimen TCGA-05-4402-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43284a2d-bc4f-4ef1-b2f8-591652897c4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4402-10A (Blood Derived Normal), aliquot TCGA-05-4402-10A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31bf0f34-6f72-450f-8aef-72107c21af1a

The open-access MAF lists 128 somatic variants for this specimen: 100 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 27, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 3, Translation Start Site 1, Splice Region 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAJB2 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 16/192 reads (8%) | catalogued as rs1182614290, COSV60675565; ClinVar: pathogenic; called by muse, mutect2
- A2M | c.2858A>G p.D953G | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59383021; called by muse, mutect2, varscan2
- ABHD1 | c.654G>C p.Q218H | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99574724; called by muse, mutect2, varscan2
- ACACB | c.5032C>A p.H1678N | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100623162; called by muse, mutect2
- ACTRT3 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100377547; called by muse, mutect2
- ADGRL2 | c.3631T>C p.S1211P (on ENST00000370717 / NM_001366005.1; = p.S1155P on NM_012302.4) | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV54652993; called by muse, mutect2
- ALDH3A1 | c.1297C>G p.L433V | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as COSV56734342; called by muse, mutect2, varscan2
- ALKBH6 | c.448G>A p.E150K (on ENST00000252984 / NM_001297701.2; = p.E178K on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as rs758745205, COSV53323967, COSV53324364; called by muse, mutect2
- ANKRD50 | c.2540G>T p.G847V | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72385055; called by muse, mutect2
- APC | c.4243dup p.S1415Kfs*8 | Frame Shift Ins (INS) | VAF 11/83 reads (13%) | catalogued as COSV57328975; called by mutect2, pindel, varscan2
- ARHGAP29 | c.3697C>G p.P1233A | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.056); catalogued as COSV53108277; called by muse, mutect2
- ARHGEF12 | c.2008G>C p.A670P | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as rs749100353, COSV63102691; called by muse, mutect2, varscan2
- ATP8A1 | c.2722C>G p.L908V | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV52528875; called by muse, mutect2
- ATR | c.3769G>C p.D1257H | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV63383962; called by muse, mutect2
- BANK1 | c.1046G>T p.C349F | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as rs532040143, COSV59838471; called by muse, mutect2, varscan2
- CACNA1D | c.3600C>G p.Y1200* (on ENST00000350061 / NM_001128840.3; = p.Y1220* on NM_000720.4) | Nonsense Mutation (SNP) | VAF 25/316 reads (8%) | catalogued as rs749592221, COSV55437808; called by muse, mutect2
- CACNA1F | c.4085G>A p.R1362Q | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs375658952, COSV59903088; called by muse, mutect2, varscan2
- CASP2 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as COSV60081396; called by muse, mutect2
- CCDC150 | c.817C>G p.Q273E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs1382583495, COSV55871812; called by muse, mutect2, varscan2
- CCDC47 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 20/230 reads (9%) | catalogued as COSV56721790; called by muse, mutect2
- CD14 | c.526A>C p.S176R | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV100117609; called by muse, mutect2, varscan2
- CD53 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54760128; called by muse, mutect2
- CDH6 | c.1519C>G p.Q507E | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV54064509, COSV54070980; called by muse, mutect2
- CEP131 | c.2117T>C p.V706A (on ENST00000269392 / NM_001319228.2; = p.V703A on NM_014984.4) | Missense Mutation (SNP) | VAF 48/548 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs761833623, COSV53950648; called by muse, mutect2
- CFAP43 | c.2875G>A p.D959N | Missense Mutation (SNP) | VAF 11/251 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV53376311; called by muse, mutect2
- CLCN1 | c.896T>G p.V299G | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58367453; called by muse, mutect2, varscan2
- CLDN15 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as rs80277788, COSV57658646; called by muse, mutect2, varscan2
- CRP | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.918); catalogued as rs867291501, COSV54812608, COSV54813231; called by muse, mutect2
- CSMD3 | c.2530C>T p.R844W (on ENST00000297405 / NM_001363185.1; = p.R740W on NM_052900.3) | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs777713609, COSV52105465; called by muse, mutect2, varscan2
- CYP26C1 | c.1224G>A p.M408I | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.1); catalogued as rs368990170, COSV53651836; called by muse, mutect2
- DCTN2 | c.634C>T p.R212W (on ENST00000548249 / NM_001261413.2; = p.R217W on NM_006400.4) | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs374804015; called by muse, mutect2
- DCTN2 | c.380C>T p.S127L (on ENST00000548249 / NM_001261413.2; = p.S132L on NM_006400.4) | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as COSV100851776; called by muse, mutect2, varscan2
- EDEM2 | c.497A>T p.Q166L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV65712566; called by muse, mutect2, varscan2
- ENC1 | c.989G>C p.R330T | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as rs1468630952, COSV100188204; called by muse, mutect2
- EXD2 | c.676C>G p.R226G (on ENST00000312994 / NM_001193362.1; = p.R101G on NM_018199.3) | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV57278078, COSV57278257; called by muse, mutect2
- F2R | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 31/266 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs774484456, COSV100058591; called by muse, mutect2, varscan2
- FOXJ3 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV62359974; called by muse, mutect2
- GAB3 | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV65818812; called by muse, mutect2
- GCH1 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as CM090760, COSV54301132; called by muse, mutect2
- GLRX3 | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as COSV58691577; called by muse, mutect2, varscan2
- GPRASP1 | c.316T>A p.S106T | Missense Mutation (SNP) | VAF 101/350 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.2); catalogued as COSV64354824; called by muse, mutect2, varscan2
- GPRIN1 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV56134750; called by muse, mutect2
- GTF2H1 | c.98G>A p.W33* | Nonsense Mutation (SNP) | VAF 8/174 reads (5%) | catalogued as COSV99786571; called by muse, mutect2
- HECTD1 | c.3845G>A p.R1282K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67945111; called by muse, mutect2, varscan2
- HECW2 | c.3531T>C p.G1177= | Splice Region (SNP) | VAF 28/136 reads (21%) | catalogued as rs986379822, COSV53649776; called by muse, mutect2, varscan2
- HIPK1 | c.54C>G p.F18L | Missense Mutation (SNP) | VAF 29/540 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV65783195; called by muse, mutect2
- INTS3 | c.3022G>A p.E1008K | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.956); catalogued as rs759263034, COSV55162151; called by muse, varscan2
- KHDRBS2 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.114); catalogued as rs944293894, COSV55428070; called by muse, mutect2, varscan2
- KIAA1549 | c.1753G>C p.D585H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV54305788; called by muse, mutect2
- KYNU | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.084); catalogued as COSV99933717; called by muse, mutect2
- LAMC2 | c.2962G>C p.D988H | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV51452545; called by muse, mutect2, varscan2
- LRCH3 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as rs1286060846, COSV58389039; called by muse, varscan2
- MAD1L1 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.278); catalogued as rs1162030516, COSV56226680; called by muse, mutect2
- MAGEE2 | c.1428C>G p.I476M | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV64897154, COSV64897312; called by muse, mutect2
- MEST | c.857T>G p.V286G | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56227529; called by muse, mutect2
- MOCOS | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV54341125; called by muse, mutect2, varscan2
- MTG1 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.075); catalogued as COSV58152569; called by muse, mutect2
- MUC17 | c.7820C>T p.T2607I | Missense Mutation (SNP) | VAF 72/440 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV60280355; called by muse, mutect2, varscan2
- MYBPC3 | c.1898A>G p.E633G | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as COSV57023217; called by muse, mutect2, varscan2
- MYH9 | c.445C>G p.H149D | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53382132; called by muse, mutect2
- NLRP13 | c.1092G>C p.K364N | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV61619972; called by muse, mutect2, varscan2
- NSG2 | c.287C>G p.T96S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.973); catalogued as COSV57456749; called by muse, mutect2, varscan2
- NUP62CL | c.545C>A p.A182E | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100991007, COSV65235215; called by muse, mutect2, varscan2
- OCA2 | c.898G>T p.V300L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV62338723; called by muse, mutect2, varscan2
- OR6C4 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101263163, COSV67793185; called by muse, mutect2
- PAK1IP1 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as COSV65435240, COSV65435681; called by muse, mutect2
- PCDHGA12 | c.2769G>C p.K923N | Missense Mutation (SNP) | VAF 8/98 reads (8%) | PolyPhen probably damaging (0.976); catalogued as COSV52743685; called by muse, mutect2
- PHLPP2 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62422577; called by muse, mutect2, varscan2
- PLEKHG6 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV50598290; called by muse, mutect2
- PLK2 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57105806; called by muse, mutect2, varscan2
- RRP8 | c.104C>G p.S35C | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV99602000; called by muse, mutect2
- SDC1 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as COSV54338796; called by muse, mutect2, varscan2
- SDHA | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.261); catalogued as COSV53765465, COSV99371566; called by muse, mutect2
- SDHAF3 | c.175-2A>G p.X59_splice | Splice Site (SNP) | VAF 8/35 reads (23%) | catalogued as COSV64490650; called by muse, mutect2
- SH2D1B | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100854732, COSV63391975; called by muse, mutect2
- SHOC2 | c.703+2T>A p.X235_splice | Splice Site (SNP) | VAF 18/43 reads (42%) | catalogued as COSV54620394, COSV99510407; called by muse, varscan2
- SLC22A8 | c.1529G>A p.W510* | Nonsense Mutation (SNP) | VAF 10/122 reads (8%) | catalogued as COSV60323747; called by muse, mutect2
- SLCO4C1 | c.1123C>G p.L375V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV60512847; called by muse, mutect2
- SLCO6A1 | c.1409T>A p.V470E | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.56); catalogued as COSV65805844; called by muse, mutect2, varscan2
- SPRYD4 | c.251C>G p.T84S | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV100358429; called by muse, mutect2
- SPTA1 | c.6585G>T p.Q2195H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63749125; called by muse, mutect2, varscan2
- TBC1D31 | c.138G>C p.L46F | Missense Mutation (SNP) | VAF 14/257 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54863814; called by muse, mutect2
- TKTL1 | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV54211798; called by muse, mutect2
- TLR7 | c.1619C>A p.P540H | Missense Mutation (SNP) | VAF 147/487 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV66123531; called by muse, mutect2, varscan2
- TLR8 | c.412C>T p.P138S (on ENST00000218032 / NM_138636.5; = p.P156S on NM_016610.4) | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as rs374687057, COSV54316458; called by muse, mutect2, varscan2
- TMEFF2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as COSV55828138; called by muse, mutect2
- TMPO | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV58460571; called by muse, mutect2
- TMPRSS11A | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1037515820, COSV58356942; called by muse, mutect2, varscan2
- TNFRSF19 | c.360-1G>C p.X120_splice | Splice Site (SNP) | VAF 6/58 reads (10%) | catalogued as COSV50311567; called by muse, mutect2
- TPH1 | c.754T>C p.C252R | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51456794; called by muse, mutect2
- TRPC4 | c.314G>C p.R105T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV58990843; called by muse, mutect2, varscan2
- TTPA | c.423G>C p.E141D | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV52645819; called by muse, mutect2, varscan2
- TYR | c.782A>C p.N261T | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.899); catalogued as COSV54470333; called by muse, mutect2, varscan2
- UBR4 | c.15508G>T p.D5170Y | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV100921437; called by muse, mutect2, varscan2
- UBR5 | c.6185G>C p.R2062T | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.916); catalogued as COSV55279192, COSV55280264; called by muse, mutect2
- USF3 | c.2339C>T p.S780L | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs750793022, COSV57069910; called by muse, mutect2
- ZFP2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as COSV100797105; called by muse, mutect2
- EGFR | c.2254_2276del p.S752Pfs*3 | Frame Shift Del (DEL) | VAF 93/193 reads (48%) | called by mutect2, pindel*
- OSGIN2 | c.1203del p.I403Yfs*8 | Frame Shift Del (DEL) | VAF 20/170 reads (12%) | called by mutect2, varscan2
- TP53 | c.518_533del p.V173Afs*69 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel
- ADAM15 | c.1018C>T p.L340= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as COSV55125299; called by muse, mutect2, varscan2
- ATP12A | c.2865G>C p.R955= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV54512506; called by muse, mutect2, varscan2
- CAPN6 | c.825G>A p.E275= | Silent (SNP) | VAF 57/702 reads (8%) | catalogued as COSV60693904; called by muse, mutect2
- CD180 | c.339G>C p.L113= | Silent (SNP) | VAF 19/196 reads (10%) | catalogued as COSV56516843; called by muse, mutect2
- COL17A1 | c.3369G>A p.L1123= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV62225301; called by muse, mutect2, varscan2
- CPT2 | c.1251C>T p.F417= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as rs576822710, COSV53758715; called by muse, mutect2, varscan2
- CSDE1 | c.1146G>A p.G382= (on ENST00000358528 / NM_001007553.3; = p.G351= on NM_007158.6) | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as COSV54738831; called by muse, mutect2
- DLEC1 | c.3390C>G p.L1130= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as COSV57295297; called by muse, mutect2
- FIBIN | c.60C>T p.F20= | Silent (SNP) | VAF 19/158 reads (12%) | catalogued as COSV59413060; called by muse, mutect2, varscan2
- HECW1 | c.3907C>T p.L1303= | Silent (SNP) | VAF 15/304 reads (5%) | catalogued as COSV67822099; called by muse, mutect2
- KIF21B | c.1188G>A p.Q396= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as COSV59752538; called by muse, mutect2, varscan2
- LRP1 | c.10335G>A p.E3445= | Silent (SNP) | VAF 13/240 reads (5%) | catalogued as COSV54502345; called by muse, mutect2
- MAST4 | c.5700G>A p.R1900= (on ENST00000403625 / NM_001164664.2; = p.R1711= on NM_015183.3) | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV55115965; called by muse, mutect2
- MYO5A | c.3618C>G p.L1206= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV62556715; called by muse, mutect2
- OR51D1 | c.528C>G p.L176= | Silent (SNP) | VAF 22/280 reads (8%) | catalogued as rs915552398, COSV62913879; called by muse, mutect2
- PRRC2C | c.4575A>G p.T1525= (on ENST00000367742; = p.T1523= on NM_015172.4) | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV58901107; called by mutect2, varscan2
- PSD4 | c.2745C>T p.P915= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs369985754, COSV99830912; called by muse, mutect2, varscan2
- PYCR3 | c.252C>G p.V84= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV55305944; called by muse, mutect2
- RNF133 | c.321G>T p.R107= | Silent (SNP) | VAF 20/272 reads (7%) | catalogued as COSV100411490, COSV100411701; called by muse, mutect2
- SERPINA5 | c.1161C>A p.P387= | Silent (SNP) | VAF 101/712 reads (14%) | catalogued as COSV61573539; called by muse, mutect2, varscan2
- SLC33A1 | c.57C>T p.F19= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1466557230, COSV63946714; called by muse, mutect2, varscan2
- SNRNP200 | c.2610C>T p.I870= | Silent (SNP) | VAF 15/182 reads (8%) | catalogued as COSV60487240; called by muse, mutect2
- SNRNP200 | c.2548C>T p.L850= | Silent (SNP) | VAF 26/360 reads (7%) | catalogued as COSV60487252; called by muse, mutect2
- TDRD7 | c.3168C>T p.V1056= | Silent (SNP) | VAF 21/162 reads (13%) | catalogued as COSV62428353; called by muse, mutect2, varscan2
- TMEM132B | c.2181C>T p.V727= | Silent (SNP) | VAF 59/210 reads (28%) | catalogued as COSV54745051; called by muse, mutect2, varscan2
- ZNF536 | c.1824G>A p.L608= | Silent (SNP) | VAF 24/178 reads (13%) | catalogued as COSV62818689; called by muse, mutect2, varscan2
- ZNF99 | c.1311C>T p.F437= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV68054786; called by muse, mutect2, varscan2
- H2BC15 | chr6:27837945 C>T | 5'Flank (SNP) | VAF 15/159 reads (9%) | catalogued as rs774976261, COSV100357057; called by muse, mutect2, varscan2
